TCGA case TCGA-CM-6678 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d7048098-09b3-4763-ad54-9c5c6fe14bc0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 63.2 years (23,070 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N1c; AJCC pathologic M: M1a; AJCC pathologic stage: Stage IVA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 335 days.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 19; Lymphatic invasion present: No; Non nodal tumor deposits: Yes; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Floxuridine; Treatment intent type: Adjuvant; Days to treatment start: 0 days; Days to treatment end: 214 days; Number of cycles: 7; Treatment dose: 475 mg; Prescribed dose: 170; Prescribed dose units: mg; Route of administration: Intrahepatic.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 17 days; Days to treatment end: 214 days; Number of cycles: 12; Treatment dose: 2,040 mg; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 30 days; Days to treatment end: 91 days; Number of cycles: 7; Treatment dose: 770 mg; Prescribed dose: 130; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Floxuridine; Days to treatment start: 275 days; Days to treatment end: 275 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Days to treatment start: 275 days; Days to treatment end: 306 days.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Liver. Age at diagnosis: 63.2 years (23,070 days); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 244 days; Treatment anatomic sites: Liver.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 0 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 122 days; Disease response: Tumor Free.
- Days to follow up: 335 days; Disease response: With Tumor.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- CEA: 286.6 ng/mL.
- KRAS mutation, nos: Positive; Mutation codon: 12.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 59 kg; Height: 157 cm; BMI: 23.9.

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CM-6678-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 1.3; Shortest dimension: 0.5.
  Slide TCGA-CM-6678-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 12.
  Slide TCGA-CM-6678-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-CM-6678-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CM-6678-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 286.6; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: Yes; KRAS mutation found: Yes; BRAF gene analysis indicator: Yes; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment 2: Pharmaceutical therapy drug name: IRINOtecan HCl.
- Drug treatment 3: Regimen number: 1; Pharmaceutical therapy drug name: Irinotecan HCL.
- Drug treatment 3, Route of administrations: Route of administration: IV.
- Drug treatment 5, Route of administrations: Route of administration: IH.
- Follow-up form 2: Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 335 days; disease-specific survival: no event (censored), 335 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 0 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CM-6678-01A-11D-1834-01): tumor purity 0.66, ploidy 2.36, whole-genome doublings 0.
